Gene-level copy-number profile of tumor specimen CUPP-B38N-TTM1-A from CCG case CUPP-B38N, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, metastatic, NOS; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage III; Age at diagnosis: 65.2 years (23,807 days).
Specimen CUPP-B38N-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 96a60576-8e9d-4fc9-9c1e-05c185cec4f7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B38N-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/3a5cacfe-9ed1-41c2-ab74-57460e2a7f06

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 833; copy number 2: 56,702; copy number 3: 725; copy number 4: 15; copy number 5: 10; copy number 6: 72; copy number 8: 1; copy number 9: 3.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,926,162–12,928,253, 1 gene (within-gene range 0–1): PRAMEF29P.
- chr1:204,603,035–204,616,565, 1 gene: AL512306.3.
- chr2:25,227,855–25,342,590, 2 genes (within-gene range 0–1): DNMT3A, MIR1301.
- chr3:50,558,025–50,571,027, 1 gene (within-gene range 0–1): C3orf18.
- chr3:126,432,796–126,434,569, 1 gene (within-gene range 0–2): AC073439.1.
- chr11:70,477,277–70,477,592, 1 gene (within-gene range 0–1): AP001271.1.
- chr14:105,597,691–105,601,728, 1 gene (within-gene range 0–2): IGHE.
- chr15:25,191,416–25,225,284, 19 genes (within-gene range 0–2): SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30.
- chr15:74,812,716–74,831,795, 2 genes (within-gene range 0–2): LMAN1L, AC091230.1.
- chr15:74,843,730–74,873,365, 1 gene: SCAMP2.
- chr18:78,795,612–78,796,672, 1 gene: AC044873.1.
- chr18:79,702,721–79,703,651, 1 gene (within-gene range 0–1): AC068473.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 86 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,938,472–13,032,130, 2 genes, copy number 9 (within-gene range 1–9): PRAMEF6, PRAMEF28P.
- chr7:38,269,491–38,300,322, 6 genes, copy number 5 (within-gene range 2–5): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr7:76,521,611–76,541,459, 4 genes, copy number 5: AC004980.4, Y_RNA, AC004980.3, SPDYE16.
- chr14:22,066,016–22,513,998, 71 genes, copy number 6 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 6: TRAC.
- chr14:105,583,731–105,588,395, 1 gene, copy number 9: IGHA2.
- chr14:105,647,924–105,649,057, 1 gene, copy number 8: COPDA1.

Autosomal genes at a single copy (total copy number 1): 832. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
